Somatic mutation profile of tumor specimen TCGA-AA-3875-01A (aliquot TCGA-AA-3875-01A-01W-0900-09) from TCGA case TCGA-AA-3875, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage I; Age at diagnosis: 78.4 years (28,640 days).
Specimen TCGA-AA-3875-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 03af39c3-447d-439b-b3a6-23a1fed46354.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3875-10A (Blood Derived Normal), aliquot TCGA-AA-3875-10A-01W-0902-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8bc75cd-1c6b-4359-9e8c-95cf701d943c

The open-access MAF lists 133 somatic variants for this specimen: 106 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 26, Nonsense Mutation 11, Frame Shift Ins 2, Splice Site 1, In Frame Del 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LAMA2 | c.7147C>T p.R2383* | Nonsense Mutation (SNP) | VAF 54/179 reads (30%) | catalogued as rs121913576, CM004723, COSV70345286, COSV70346485; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 15/52 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC004922.1 | c.425G>A p.R142H | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); catalogued as rs777116048, COSV53559736; called by muse, mutect2, varscan2
- ARMC3 | c.2465G>C p.R822T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53069360; called by muse, mutect2, varscan2
- ASB8 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 41/136 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.685); catalogued as rs868063048, COSV58352164; called by muse, mutect2, varscan2
- ATG14 | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV55958645; called by muse, mutect2, varscan2
- CD2BP2 | c.8A>C p.K3T | Missense Mutation (SNP) | VAF 34/225 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59770098; called by muse, mutect2, varscan2
- CELSR1 | c.4738G>A p.A1580T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs375003533, COSV53101868; called by muse, mutect2, varscan2
- CEP152 | c.2305C>G p.L769V | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.603); catalogued as COSV57859772; called by muse, mutect2
- CRAMP1 | c.2387C>T p.P796L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as rs915938562, COSV51966996; called by muse, mutect2
- CSMD2 | c.6661C>T p.R2221C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs144426100, COSV53973745; called by muse, mutect2
- CYTL1 | c.294G>T p.K98N | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.098); catalogued as COSV57038440; called by muse, mutect2, varscan2
- DCHS1 | c.2074G>T p.A692S | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV55044391; called by muse, mutect2, varscan2
- DENND5A | c.2542C>T p.R848C | Missense Mutation (SNP) | VAF 43/121 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs148317700; called by muse, mutect2, varscan2
- DNAH5 | c.10309C>A p.H3437N | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV54258130; called by muse, mutect2, varscan2
- DNM1L | c.284A>G p.H95R | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56778846; called by muse, mutect2, varscan2
- EPB41L5 | c.2079A>T p.K693N | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as COSV55359109; called by muse, mutect2
- ERBB4 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as rs1319320879, COSV53526682; called by muse, mutect2, varscan2
- FBN1 | c.8188C>T p.R2730W | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1371152380, COSV57311133; ClinVar: uncertain significance; called by muse, varscan2
- FBN1 | c.8071G>C p.G2691R | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as rs145105768, CM145809, COSV57333175; called by muse, varscan2
- FBXL7 | c.916C>T p.R306C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1239863082, COSV61640555; called by muse, mutect2, varscan2
- FHIT | c.289G>A p.V97I | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.011); catalogued as rs139666727, COSV59288244; called by muse, mutect2, varscan2
- FRMD3 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs372201657; called by muse, mutect2, varscan2
- GRIP1 | c.1276C>T p.P426S (on ENST00000359742 / NM_001379345.1; = p.P374S on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.293); catalogued as rs764803577, COSV54046708; called by muse, mutect2, varscan2
- HAS2 | c.1585C>A p.L529M | Missense Mutation (SNP) | VAF 16/417 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.141); catalogued as COSV100391469, COSV58265340; called by muse, mutect2
- HGF | c.482+1G>T p.X161_splice | Splice Site (SNP) | VAF 13/78 reads (17%) | catalogued as COSV55945112, COSV55953608; called by muse, mutect2, varscan2
- HTATSF1 | c.1988C>T p.A663V | Missense Mutation (SNP) | VAF 172/596 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1435332332, COSV54479813; called by muse, mutect2, varscan2
- JHY | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 40/106 reads (38%) | catalogued as rs773572521, COSV56222061; called by muse, mutect2, varscan2
- KIAA0319 | c.857C>A p.T286N | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV100985233; called by muse, mutect2
- KIAA1549L | c.137G>T p.G46V (on ENST00000321505; = p.G343V on NM_012194.3) | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); catalogued as COSV55782565; called by muse, mutect2, varscan2
- KRT3 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs530962648, COSV58817332; called by muse, mutect2, varscan2
- LAMB1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs1239012672, COSV55971470; called by muse, mutect2, varscan2
- LIFR | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 76/336 reads (23%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs373771721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP3K14 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs199558586, COSV100766396; called by muse, mutect2, varscan2
- MAPKBP1 | c.985G>A p.V329I (on ENST00000456763 / NM_001128608.2; = p.V323I on NM_014994.3) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs374717785; called by muse, mutect2, varscan2
- MAPKBP1 | c.1216C>T p.Q406* (on ENST00000456763 / NM_001128608.2; = p.Q400* on NM_014994.3) | Nonsense Mutation (SNP) | VAF 14/45 reads (31%) | catalogued as COSV52967140; called by muse, mutect2, varscan2
- MBTPS1 | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.874); catalogued as COSV58573052; called by muse, mutect2, varscan2
- MYOCD | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 61/186 reads (33%) | catalogued as COSV58514031; called by muse, mutect2, varscan2
- NAALAD2 | c.725C>A p.A242E | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV58967203; called by muse, mutect2
- NAALADL2 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs372908344, COSV69155077, COSV69161223; called by muse, mutect2, varscan2
- NFKBIB | c.547T>G p.S183A | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV58005581; called by muse, mutect2, varscan2
- NGB | c.436C>T p.R146* | Nonsense Mutation (SNP) | VAF 9/50 reads (18%) | catalogued as rs1452319933, COSV53611736; called by muse, mutect2, varscan2
- NHS | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 120/545 reads (22%) | catalogued as COSV66272477; called by muse, mutect2, varscan2
- NOS1 | c.2312C>T p.S771L | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs150227193, COSV57608175; called by muse, mutect2, varscan2
- NPAS3 | c.181C>T p.R61C (on ENST00000356141 / NM_001164749.2; = p.R31C on NM_022123.3) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759518256, COSV58091462; called by muse, mutect2
- NRXN1 | c.4315C>T p.R1439* | Nonsense Mutation (SNP) | VAF 41/166 reads (25%) | catalogued as rs1331703447, COSV60528047; called by muse, mutect2, varscan2
- NVL | c.2320G>A p.V774I | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as COSV55877038; called by muse, mutect2, varscan2
- OLFML1 | c.682C>G p.H228D | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV55083656; called by muse, mutect2
- OR10AG1 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.1); catalogued as COSV56635359; called by muse, mutect2, varscan2
- OR10H5 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV58279441; called by muse, mutect2, varscan2
- OR2T29 | c.382G>A p.V128M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as rs1284986887, COSV100148184; called by mutect2, varscan2
- OR4X1 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 68/219 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60724302; called by muse, mutect2, varscan2
- OR5I1 | c.539dup p.C181Lfs*2 | Frame Shift Ins (INS) | VAF 32/137 reads (23%) | catalogued as rs757816304; called by mutect2, pindel, varscan2
- OR5M1 | c.454G>C p.G152R | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101591533; called by muse, mutect2
- PCDHA2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV65370933; called by muse, mutect2, varscan2
- PDE10A | c.1766C>T p.S589F | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63107947; called by muse, mutect2, varscan2
- PRAMEF19 | c.143G>A p.C48Y | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1412539201; called by muse, mutect2, varscan2
- PRDM12 | c.472C>T p.R158W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs371786311; called by muse, mutect2, varscan2
- PRMT3 | c.343T>A p.W115R | Missense Mutation (SNP) | VAF 6/136 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100423673; called by muse, mutect2
- PRSS55 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as rs202134590, COSV60809581; called by muse, mutect2, varscan2
- PTBP2 | c.34A>G p.I12V (on ENST00000426398 / NM_001300986.2; = p.I4V on NM_021190.4) | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV64626852; called by muse, mutect2, varscan2
- RAB25 | c.70G>A p.G24R | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV63108897; called by muse, mutect2, varscan2
- RET | c.2308C>T p.R770* | Nonsense Mutation (SNP) | VAF 5/20 reads (25%) | catalogued as rs775711017, COSV60690064, COSV60700121; called by muse, mutect2, varscan2
- ROS1 | c.5476T>C p.F1826L | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63862701; called by muse, mutect2, varscan2
- RPS16 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV52240061; called by muse, mutect2, varscan2
- RYR3 | c.1846C>A p.Q616K | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66811332; called by muse, mutect2, varscan2
- SARDH | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.234); catalogued as rs760282297, COSV53836094; called by muse, mutect2, varscan2
- SCN2A | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs149024364, COSV51858272; called by muse, mutect2, varscan2
- SDK2 | c.1976G>A p.R659H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs367622362; called by muse, mutect2, varscan2
- SDSL | c.801T>A p.D267E | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV61885496; called by muse, mutect2, varscan2
- SEMA4D | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59402159; called by muse, mutect2, varscan2
- SH3PXD2A | c.1537C>T p.R513C (on ENST00000369774 / NM_001365079.1; = p.R485C on NM_014631.2) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs751092364, COSV60121245; called by muse, mutect2, varscan2
- SH3TC2 | c.158C>T p.T53I | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV60468602; called by muse, mutect2, varscan2
- SIX1 | c.603C>A p.N201K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.81); PolyPhen benign (0.015); catalogued as COSV55960122, COSV55961516; called by muse, mutect2, varscan2
- SLC8A1 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1231443890, COSV60470187, COSV60474519; called by muse, mutect2, varscan2
- SON | c.2876C>T p.T959I | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.703); catalogued as COSV51672463; called by muse, mutect2
- SRRM2 | c.1751C>T p.S584F | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57081783; called by muse, mutect2, varscan2
- STAG1 | c.524G>T p.R175L | Missense Mutation (SNP) | VAF 26/292 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52626117; called by muse, mutect2
- STOX2 | c.2096G>T p.S699I | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1397594885, COSV57857441; called by muse, mutect2, varscan2
- SYNE1 | c.15875C>T p.P5292L (on ENST00000367255 / NM_182961.4; = p.P5221L on NM_033071.3) | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.283); catalogued as rs200626370, COSV54927845; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.4204G>A p.E1402K (on ENST00000367255 / NM_182961.4; = p.E1409K on NM_033071.3) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54911543; called by muse, mutect2, varscan2
- SYNE1 | c.508C>T p.R170W (on ENST00000367255 / NM_182961.4; = p.R177W on NM_033071.3) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777175001, COSV54897233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF1A | c.1219G>A p.A407T | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.651); catalogued as COSV61920305; called by mutect2, varscan2
- TAF7L | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 70/207 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV63299956; called by muse, mutect2, varscan2
- TBC1D25 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV65124882; called by muse, mutect2, varscan2
- TBL1X | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.429); catalogued as COSV54283329; called by muse, mutect2, varscan2
- TBX20 | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1215522044, COSV68784832; called by muse, mutect2, varscan2
- THSD7B | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 50/197 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs764321163, COSV55714470; called by muse, mutect2, varscan2
- TNFSF14 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs772753769, COSV55590283; called by muse, mutect2, varscan2
- TNFSF8 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV56342871; called by muse, mutect2, varscan2
- TNKS1BP1 | c.4109T>C p.V1370A | Missense Mutation (SNP) | VAF 46/319 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as COSV64103033; called by muse, varscan2
- TRIM55 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.015); catalogued as rs1045777754, COSV52549278; called by muse, mutect2, varscan2
- TUBA3D | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); catalogued as rs752428849, COSV58311623; called by muse, mutect2, varscan2
- UBE3A | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 27/250 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.073); catalogued as COSV51668628; called by muse, mutect2, varscan2
- UGGT2 | c.3370A>G p.I1124V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs778195073, COSV65080442; called by muse, mutect2, varscan2
- UNC13C | c.5740C>T p.R1914* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV52933575; called by muse, mutect2, varscan2
- WNK3 | c.2592G>C p.Q864H | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV63616331; called by muse, mutect2
- ZEB2 | c.1876G>A p.G626R | Missense Mutation (SNP) | VAF 50/185 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.336); catalogued as rs727504224, CM097142, COSV57968259; ClinVar: uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ZFC3H1 | c.150A>T p.L50F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen probably damaging (0.969); catalogued as rs372412639; called by muse, mutect2, varscan2
- ZFHX4 | c.3172G>T p.V1058F | Missense Mutation (SNP) | VAF 45/157 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV51502045; called by muse, mutect2, varscan2
- ZMYM4 | c.2849C>T p.P950L | Missense Mutation (SNP) | VAF 56/207 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58919005; called by muse, mutect2, varscan2
- ZNF628 | c.2762A>T p.D921V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV52702976; called by muse, varscan2
- ZNF808 | c.2408A>T p.N803I | Missense Mutation (SNP) | VAF 62/731 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as COSV63122089; called by muse, mutect2
- ASXL2 | c.1396dup p.S466Ffs*8 | Frame Shift Ins (INS) | VAF 85/331 reads (26%) | called by mutect2, pindel, varscan2
- SLCO1A2 | c.460_498del p.K154_I166del | In Frame Del (DEL) | VAF 18/188 reads (10%) | called by mutect2, pindel
- VPS13C | c.7387del p.E2463Nfs*18 (on ENST00000644861 / NM_020821.3; = p.E2420Nfs*18 on NM_017684.5) | Frame Shift Del (DEL) | VAF 31/140 reads (22%) | called by mutect2, pindel, varscan2
- AMPH | c.348G>T p.G116= | Silent (SNP) | VAF 20/456 reads (4%) | catalogued as COSV100341016; called by muse, mutect2
- ANGPTL1 | c.618A>C p.R206= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as COSV52368483; called by muse, mutect2, varscan2
- ARSF | c.1599G>A p.K533= | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV63840573; called by muse, mutect2, varscan2
- ASPN | c.250C>A p.R84= | Silent (SNP) | VAF 35/122 reads (29%) | catalogued as COSV65016788; called by muse, mutect2, varscan2
- CECR2 | c.2022G>A p.P674= (on ENST00000342247 / NM_001290047.2; = p.P491= on NM_001290046.1) | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs540911813, COSV52850170, COSV99379336; called by muse, mutect2, varscan2
- CENPF | c.4638G>A p.A1546= | Silent (SNP) | VAF 21/94 reads (22%) | catalogued as rs564882822, COSV65274154; called by muse, mutect2, varscan2
- CLP1 | c.555G>A p.V185= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV57056025; called by muse, mutect2, varscan2
- CNTNAP4 | c.1911C>T p.N637= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs148411005; called by muse, mutect2, varscan2
- COL1A2 | c.2151C>T p.V717= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as rs763380136, COSV51968026; called by muse, mutect2, varscan2
- CORIN | c.2748G>A p.P916= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as rs750625096, COSV56701218, COSV99903654; called by muse, mutect2, varscan2
- DST | c.16266G>C p.S5422= (on ENST00000361203 / NM_001374722.1; = p.S3010= on NM_015548.5) | Silent (SNP) | VAF 19/140 reads (14%) | catalogued as COSV54995038, COSV55046248; called by muse, mutect2, varscan2
- EPHA7 | c.2889G>T p.V963= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs767240586, COSV65193684; called by muse, mutect2, varscan2
- FCRL3 | c.618C>A p.P206= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as COSV63845589; called by muse, mutect2, varscan2
- FCRL3 | c.447C>A p.I149= | Silent (SNP) | VAF 47/206 reads (23%) | catalogued as COSV63841823, COSV63845593; called by muse, mutect2, varscan2
- GRIK5 | c.1461G>A p.E487= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV53487322; called by muse, mutect2, varscan2
- KCNA1 | c.267C>T p.F89= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs371963908; called by muse, mutect2, varscan2
- MAGEC1 | c.2748G>A p.A916= | Silent (SNP) | VAF 111/422 reads (26%) | catalogued as rs749815753, COSV53572525; called by muse, mutect2, varscan2
- MAP2 | c.3675C>A p.I1225= | Silent (SNP) | VAF 35/146 reads (24%) | catalogued as rs1392337437, COSV52282177, COSV52311864; called by muse, mutect2, varscan2
- MAPT | c.24C>T p.F8= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs886700939, COSV52240234; called by muse, mutect2, varscan2
- MYL1 | c.66G>A p.P22= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs370260390; called by muse, mutect2, varscan2
- NLRP9 | c.1563G>A p.Q521= | Silent (SNP) | VAF 53/262 reads (20%) | catalogued as COSV60468740; called by muse, mutect2, varscan2
- OXR1 | c.393C>G p.S131= (on ENST00000442977 / NM_001198532.1; = p.S130= on NM_018002.3) | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV56337872; called by muse, mutect2, varscan2
- P2RY14 | c.318C>T p.Y106= | Silent (SNP) | VAF 70/266 reads (26%) | catalogued as rs753882142, COSV56389598; called by muse, mutect2, varscan2
- PCDHA2 | c.2004G>A p.S668= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs369554786; called by muse, mutect2, varscan2
- RBM28 | c.879C>T p.S293= | Silent (SNP) | VAF 33/279 reads (12%) | catalogued as rs748735152, COSV56165339; called by muse, mutect2, varscan2
- TENM1 | c.72C>A p.T24= | Silent (SNP) | VAF 141/668 reads (21%) | catalogued as COSV64446833; called by muse, mutect2, varscan2
- SNORD115-17 | n.60T>A | RNA (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
